Gene-level copy-number profile of tumor specimen TCGA-L5-A4OQ-01A from TCGA case TCGA-L5-A4OQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 75.5 years (27,565 days).
Specimen TCGA-L5-A4OQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.742a12b8-fdbd-4f1a-a83e-ab989f025d48.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OQ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/9c09482c-5905-473b-85c6-3dcdd13b480f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,590; copy number 2: 41,866; copy number 3: 11,073; copy number 4: 3,077; copy number 5: 922; copy number 6: 146; copy number 7: 98; copy number 8: 25; copy number 9: 5; copy number 13: 4.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr5:60,021,249–60,304,151, 2 genes: AC034234.1, RNU6-806P.
- chr11:80,957,317–81,040,236, 2 genes: AP003398.1, AP003398.2.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,200 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,838,110–40,097,260, 9 genes, copy number 7: TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1.
- chr1:53,841,547–54,200,073, 16 genes, copy number 6 (within-gene range 2–6): AL049745.2, YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2.
- chr1:151,254,709–151,583,583, 19 genes, copy number 5 (within-gene range 2–5): PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1.
- chr2:86,135,870–86,563,479, 11 genes, copy number 7 (within-gene range 3–7): SNORD94, IMMT, Y_RNA, MIR4779, AC009309.1, MRPL35, REEP1, U8, AC009408.1, KDM3A, CHMP3.
- chr2:86,515,204–86,515,308, 1 gene, copy number 7: RNU6-640P.
- chr2:97,713,576–98,936,259, 18 genes, copy number 6: ZAP70, TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1, CNGA3, AC092675.2, INPP4A, COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P.
- chr2:102,311,502–105,962,386, 63 genes, copy number 5–7 (broad region; genes not listed).
- chr2:111,429,324–112,119,318, 19 genes, copy number 6: AC017002.3, AC017002.2, SOCAR, DBF4P2, AC017002.1, ANAPC1, RPL34P8, AC093166.1, CENPNP2, MIR4771-2, AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1, AC093675.1, TMEM87B, AC093675.2.
- chr2:174,547,141–174,776,720, 1 gene, copy number 9 (within-gene range 4–9): AC010894.2.
- chr2:174,559,572–174,682,916, 1 gene, copy number 9 (within-gene range 4–9): WIPF1.
- chr2:174,719,908–179,285,707, 109 genes, copy number 5–13 (broad region; genes not listed).
- chr3:47,164,186–47,580,792, 13 genes, copy number 5–6 (within-gene range 2–6): KIF9-AS1, KIF9, SNORD13P3, KLHL18, AC104447.1, AC099778.1, PTPN23, SCAP, AC099778.2, ELP6, BOLA2P2, RN7SL870P, CSPG5.
- chr3:47,601,715–47,604,677, 1 gene, copy number 6: AC112512.1.
- chr5:127,588,746–128,189,677, 9 genes, copy number 5 (within-gene range 5–18): AC010424.3, CTXN3, AC022118.1, CCDC192, CUL1P1, AC068658.1, LINC01184, SLC12A2, KDELC1P1.
- chr5:128,371,099–128,371,212, 1 gene, copy number 5: Y_RNA.
- chr7:996,986–1,138,260, 1 gene, copy number 5 (within-gene range 3–5): C7orf50.
- chr7:1,029,025–1,747,954, 25 genes, copy number 5: AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr7:105,876,796–106,315,743, 8 genes, copy number 5: CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2.
- chr8:39,902,275–40,172,612, 10 genes, copy number 5: IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1.
- chr8:61,500,556–61,944,180, 9 genes, copy number 6 (within-gene range 3–6): ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3.
- chr8:126,556,323–127,419,050, 1 gene, copy number 6 (within-gene range 3–6): PCAT1.
- chr8:127,072,694–128,187,101, 21 genes, copy number 6 (within-gene range 3–6): CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P.
- chr9:113,876,282–114,312,511, 5 genes, copy number 5 (within-gene range 3–5): ZNF618, AMBP, KIF12, COL27A1, MIR455.
- chr9:128,039,135–128,109,245, 4 genes, copy number 5 (within-gene range 3–5): AL360268.2, NAIF1, SLC25A25, AL360268.1.
- chr11:924,894–1,012,245, 1 gene, copy number 5 (within-gene range 2–5): AP2A2.
- chr11:1,012,823–1,220,242, 5 genes, copy number 5: MUC6, LINC02688, MUC2, MUC5AC, AC061979.1.
- chr11:75,100,563–75,669,120, 22 genes, copy number 5 (within-gene range 3–5): SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL, ARRB1, AP001972.1, AP001972.5, AP001972.2, MIR326, RPS3, SNORD15A, SNORD15B, KLHL35, GDPD5, AP002815.1, SERPINH1, AP001922.5, MAP6, AP001922.6, AP001922.2, AP001922.4.
- chr13:68,289,679–71,914,178, 27 genes, copy number 5: ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21.
- chr17:29,071,122–29,180,398, 1 gene, copy number 7 (within-gene range 3–7): MYO18A.
- chr17:29,140,483–29,294,148, 5 genes, copy number 7: AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2.
- chr17:37,084,992–40,284,136, 124 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:63,009,556–63,427,699, 1 gene, copy number 5 (within-gene range 3–5): TANC2.
- chr17:63,117,019–66,278,664, 106 genes, copy number 5 (broad region; genes not listed).
- chr17:66,364,029–66,416,854, 2 genes, copy number 5 (within-gene range 2–5): RN7SL735P, PRKCA-AS1.
- chr19:29,923,644–30,016,612, 1 gene, copy number 6 (within-gene range 4–6): URI1.
- chr19:30,028,741–34,951,205, 119 genes, copy number 5–6 (broad region; genes not listed).
- chr20:24,931,840–26,251,546, 50 genes, copy number 5: AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr20:35,115,364–35,700,984, 33 genes, copy number 6: EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1.
- chr20:37,903,111–50,691,542, 328 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
